CCDI case PBBKTD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f351f7fb-776e-45aa-a12d-5be5e7f85498

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,273 days).

Biospecimens (3 samples)
- Sample 0DB2AO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB2AV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB2B7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
